Somatic mutation profile of tumor specimen TCGA-EB-A44P-01A (aliquot TCGA-EB-A44P-01A-11D-A25O-08) from TCGA case TCGA-EB-A44P, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 58.9 years (21,519 days).
Specimen TCGA-EB-A44P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6b675d9-3e28-4c27-84ab-3d73b77b8bb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A44P-10A (Blood Derived Normal), aliquot TCGA-EB-A44P-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c14aec7c-ff43-4628-9e9b-cf6f32c9c2a9

The open-access MAF lists 411 somatic variants for this specimen: 253 protein-altering or splice-affecting, 147 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 147, Nonsense Mutation 9, Splice Region 4, 3'UTR 4, RNA 3, Intron 3, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 22/28 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- COL4A4 | c.4522G>A p.G1508S | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1003748020, CM1312568, COSV61637473; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.210-2A>G p.X70_splice | Splice Site (SNP) | VAF 14/19 reads (74%) | hotspot (GDC flag); catalogued as rs1564828914, CD109151, COSV64302273; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2170G>A p.D724N (on ENST00000404938 / NM_001163941.2; = p.D279N on NM_178559.6) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV51722951; called by muse, mutect2, varscan2
- ABCC9 | c.3381G>A p.M1127I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53962382; called by muse, mutect2, varscan2
- ACKR2 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56178848; called by muse, mutect2, varscan2
- ACSL5 | c.1648G>A p.G550R (on ENST00000354273; = p.G606R on NM_016234.3) | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61133501; called by muse, mutect2, varscan2
- ACSM1 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs146842441, COSV54632756, COSV54637011; called by muse, mutect2, varscan2
- ACSM3 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55501173, COSV55504773; called by muse, mutect2, varscan2
- ACTRT1 | c.304A>C p.S102R | Missense Mutation (SNP) | VAF 130/310 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.779); catalogued as COSV64420197; called by muse, mutect2, varscan2
- ADAMTS20 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV67130605, COSV67134713; called by muse, mutect2, varscan2
- ADCY4 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV100156144, COSV100156926; called by muse, mutect2, varscan2
- ADCY7 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426655705, COSV54269386; called by muse, mutect2, varscan2
- ADGRV1 | c.11654C>G p.S3885C | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.785); catalogued as COSV67996973; called by muse, mutect2, varscan2
- AFF3 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV57852663; called by muse, mutect2, varscan2
- AKR1B15 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs866009184, COSV71152976; called by muse, mutect2, varscan2
- ALG3 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as rs756802179, COSV56614909; called by muse, mutect2, varscan2
- ANAPC1 | c.1633C>T p.L545F | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.121); catalogued as COSV61980127; called by muse, mutect2, varscan2
- ANKAR | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55619266; called by muse, mutect2, varscan2
- ANXA4 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV57003814; called by muse, mutect2, varscan2
- ARHGAP44 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV52404572; called by muse, mutect2, varscan2
- ARNT | c.1803G>A p.R601= | Splice Region (SNP) | VAF 12/29 reads (41%) | catalogued as COSV62232682; called by muse, mutect2, varscan2
- ATG9B | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52504897, COSV52511586; called by muse, mutect2
- ATP8B4 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99463381; called by muse, mutect2
- ATP8B4 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99463390; called by muse, mutect2
- ATP9A | c.2585C>T p.S862F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV58773072; called by muse, mutect2, varscan2
- B4GALNT4 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs746496907, COSV57327165; called by muse, mutect2
- BAHD1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372566268, COSV69084755; called by muse, mutect2, varscan2
- BBOF1 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV67455806; called by muse, mutect2, varscan2
- BRD4 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs149454272; called by muse, mutect2, varscan2
- BRIP1 | c.2684C>T p.S895F | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV52010747; called by muse, mutect2, varscan2
- C1QTNF9 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs767328235, COSV59658375; called by muse, mutect2, varscan2
- CACNA1H | c.3712G>A p.D1238N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV62006862; called by muse, mutect2, varscan2
- CC2D1A | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100528214; called by muse, mutect2, varscan2
- CC2D1A | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV100528216; called by muse, mutect2, varscan2
- CCNJL | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV57447529; called by muse, mutect2, varscan2
- CD1C | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63807935; called by muse, mutect2, varscan2
- CD86 | c.360G>A p.M120I (on ENST00000330540 / NM_175862.5; = p.M114I on NM_006889.4) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV52608624; called by muse, mutect2, varscan2
- CDADC1 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV99212525; called by muse, mutect2, varscan2
- CDH4 | c.1055T>C p.V352A | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64678934; called by muse, mutect2, varscan2
- CDR1 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.539); catalogued as rs1478287567, COSV65164604; called by muse, mutect2, varscan2
- CEP170B | c.875C>T p.S292F (on ENST00000453495; = p.S221F on NM_015005.3) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV69025435, COSV69027009; called by muse, mutect2
- CFHR2 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775004070, COSV66382446; called by muse, mutect2, varscan2
- CLCA2 | c.2747T>G p.I916S | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV65289135; called by muse, mutect2, varscan2
- CNDP1 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62595680; called by muse, mutect2, varscan2
- CNTNAP5 | c.3834A>T p.E1278D | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV70517631; called by muse, mutect2, varscan2
- COL4A5 | c.4006G>A p.G1336R | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as CM101185, COSV60374425; called by muse, mutect2, varscan2
- COL7A1 | c.7238G>A p.G2413E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM060938, COSV60404474; called by muse, mutect2, varscan2
- CPS1 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs1179804867, COSV51806010, COSV51807744; called by muse, mutect2, varscan2
- CSN2 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV61992788; called by muse, mutect2, varscan2
- CSTF3 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV60615261; called by muse, mutect2, varscan2
- CT55 | c.466T>C p.S156P | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.329); catalogued as COSV52279207; called by muse, mutect2, varscan2
- CWH43 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV56944723; called by muse, mutect2, varscan2
- CYP4F12 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61177175; called by muse, mutect2, varscan2
- CYRIA | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.142); catalogued as COSV62867684; called by muse, mutect2, varscan2
- DCAF8L1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV71595574; called by muse, mutect2, varscan2
- DDIAS | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as rs1481559101, COSV61273578; called by muse, mutect2, varscan2
- DDX43 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.042); catalogued as rs1314037211, COSV64838141; called by muse, mutect2, varscan2
- DGKG | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV53974543; called by muse, mutect2
- DIP2A | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1177045654, COSV100595118; called by muse, mutect2
- DNAH11 | c.9714G>A p.W3238* | Nonsense Mutation (SNP) | VAF 52/126 reads (41%) | catalogued as rs1364742530, COSV60987110; called by muse, mutect2, varscan2
- DNAI4 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV64024332; called by muse, mutect2, varscan2
- DOCK2 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV56956974; called by muse, mutect2, varscan2
- DPM1 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as COSV100857664; called by muse, mutect2, varscan2
- DPYSL3 | c.1526C>A p.T509N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs990783323, COSV58332021; called by muse, mutect2, varscan2
- EGFR | c.3533C>T p.P1178L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV51857489; called by muse, mutect2, varscan2
- ELOVL3 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.52); PolyPhen benign (0.06); catalogued as rs1348912397, COSV64175148; called by muse, mutect2, varscan2
- ELP1 | c.3556A>T p.N1186Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as COSV65900449; called by muse, mutect2, varscan2
- ENPP5 | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV57910287; called by muse, mutect2, varscan2
- EYS | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.333); catalogued as COSV61002551; called by muse, mutect2, varscan2
- FAM221B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65073698; called by muse, mutect2, varscan2
- FAM83F | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.081); catalogued as COSV100328814; called by muse, mutect2, varscan2
- FAM83F | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100328817; called by muse, mutect2, varscan2
- FAM83G | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs769892325, COSV58763008; called by muse, mutect2, varscan2
- FAM83G | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58763014; called by muse, mutect2, varscan2
- FAT4 | c.13463G>A p.G4488E | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as rs1482333544, COSV58713679; called by muse, mutect2, varscan2
- FLG | c.5816C>T p.S1939F | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs765230314, COSV64251850; called by muse, mutect2, varscan2
- FMO2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.498); catalogued as rs145420492, COSV52947781; called by muse, mutect2, varscan2
- FRMPD3 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99345569; called by muse, mutect2, varscan2
- GABRG1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV54950130, COSV99778230; called by muse, mutect2, varscan2
- GC | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV56736620; called by muse, mutect2, varscan2
- GCNT1 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV65058861; called by muse, mutect2, varscan2
- GCNT1 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.792); catalogued as rs955606301, COSV100946403; called by muse, mutect2, varscan2
- GIMAP8 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs750008473, COSV56231017; called by muse, mutect2, varscan2
- GLI2 | c.1493C>T p.S498F (on ENST00000361492 / NM_001374353.1; = p.S515F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58053337; called by muse, mutect2, varscan2
- GPC4 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV63700245; called by muse, mutect2, varscan2
- GPR148 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV59309253, COSV59309948; called by muse, mutect2, varscan2
- GPRC6A | c.1850G>A p.R617K | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as rs775948980, COSV59956547; called by muse, mutect2, varscan2
- HCN1 | c.2659G>T p.A887S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.012); catalogued as COSV57542046; called by muse, mutect2, varscan2
- HDGFL1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57753377; called by muse, varscan2
- HDGFL1 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV57752718, COSV57753391; called by muse, varscan2
- HEPACAM | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53433025, COSV53433057; called by muse, mutect2, varscan2
- HEPHL1 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV59893480; called by muse, mutect2, varscan2
- HNF4G | c.226G>A p.G76R (on ENST00000354370 / NM_001330561.2; = p.G123R on NM_004133.5) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62971797; called by muse, mutect2, varscan2
- HTR1D | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58449679; called by muse, mutect2, varscan2
- HYDIN | c.14014G>A p.G4672R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66642913; called by muse, mutect2, varscan2
- IFNA1 | c.484T>A p.C162S | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772355393, COSV52806770; called by muse, mutect2, varscan2
- IGLL1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.043); catalogued as rs767982337, COSV50770422; called by muse, mutect2, varscan2
- IL25 | c.280T>C p.L94= | Splice Region (SNP) | VAF 63/194 reads (32%) | catalogued as COSV59308495; called by muse, mutect2, varscan2
- IL7R | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs200772681, COSV57407732; called by muse, mutect2, varscan2
- INTS6 | c.1513C>T p.L505F | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV60881110; called by muse, mutect2, varscan2
- KASH5 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs757572871, COSV71358558; called by muse, mutect2, varscan2
- KCTD2 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100483219; called by muse, mutect2, varscan2
- KDR | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55769015; called by muse, mutect2, varscan2
- KIAA1109 | c.13524G>A p.M4508I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52697159; called by muse, mutect2, varscan2
- KIAA1755 | c.1818G>A p.W606* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV54081794; called by muse, mutect2, varscan2
- KIF27 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs898974916, COSV99926583; called by muse, mutect2, varscan2
- KIF27 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV52831830; called by muse, mutect2
- KIR3DL3 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756426142; called by muse, mutect2, varscan2
- KLHDC7A | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV68771300; called by muse, mutect2, varscan2
- KLHDC7A | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1553122963, COSV68769075; called by muse, mutect2, varscan2
- LBX1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as COSV64622230, COSV64622249; called by muse, mutect2, varscan2
- LCT | c.5335+1G>A p.X1779_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99928471; called by muse, mutect2, varscan2
- LCT | c.5335G>A p.A1779T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV99928472; called by muse, mutect2, varscan2
- LPCAT4 | c.1295G>A p.G432D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.057); catalogued as COSV100148812; called by muse, mutect2, varscan2
- LRG1 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs912162725, COSV56706446; called by muse, mutect2, varscan2
- LRP1B | c.11620C>T p.Q3874* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as COSV67213919; called by muse, mutect2, varscan2
- LY6K | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as rs1172467075, COSV52832110; called by muse, mutect2, varscan2
- MAP2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1439637960, COSV52311922; called by muse, mutect2, varscan2
- MBD3L1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.89); catalogued as rs1401687094, COSV59776703; called by muse, mutect2, varscan2
- MIA3 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV60519226; called by muse, mutect2, varscan2
- MKI67 | c.7388C>T p.S2463F | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV64077627; called by muse, mutect2, varscan2
- MROH5 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs1399033910, COSV71302330; called by muse, mutect2, varscan2
- MS4A1 | c.248C>A p.T83N | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.599); catalogued as COSV61943228; called by muse, mutect2, varscan2
- MSI2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV52354941; called by muse, mutect2, varscan2
- MUC3A | c.7766G>A p.G2589E | Missense Mutation (SNP) | VAF 96/422 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs761824690, COSV60226325; called by muse, mutect2, varscan2
- MXRA5 | c.8194C>T p.P2732S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54254302; called by muse, mutect2, varscan2
- MYH1 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs780763560, COSV56843727, COSV56851492; called by muse, mutect2, varscan2
- MYH13 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV52846304; called by muse, mutect2, varscan2
- MYO5B | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53233953; called by muse, mutect2, varscan2
- MYO7B | c.4579G>A p.D1527N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774335797, COSV67353021; called by muse, mutect2, varscan2
- MYT1 | c.2589G>A p.R863= | Splice Region (SNP) | VAF 7/22 reads (32%) | catalogued as COSV60515665; called by muse, mutect2, varscan2
- NCAM1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57520457, COSV57527163; called by muse, mutect2, varscan2
- NCKAP1L | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs267603546, COSV53213625; called by muse, mutect2
- NCKAP5 | c.2807C>T p.S936F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV58480606; called by muse, mutect2, varscan2
- NEU2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52091559; called by muse, mutect2, varscan2
- NIPBL | c.2177A>T p.K726I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV56969507; called by muse, mutect2, varscan2
- NLGN4X | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1019642795, COSV52041085; called by muse, mutect2, varscan2
- NLRP5 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs774526318, COSV66765120; called by muse, mutect2, varscan2
- NOS1 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 113/283 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1042913420, COSV57606613; called by muse, mutect2, varscan2
- NPC1 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs1555637232, COSV52579221; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NPR2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV61313665; called by muse, mutect2, varscan2
- NRG2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as rs762781144, COSV56841740; called by muse, mutect2, varscan2
- NUMA1 | c.6049C>T p.R2017* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as rs763458607, COSV52623002, COSV99475038; called by muse, mutect2, varscan2
- OR2Z1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60693530; called by muse, mutect2, varscan2
- OR4N2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60050301; called by muse, mutect2, varscan2
- OR51A7 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201363687, COSV63789088; called by muse, mutect2, varscan2
- OR51G1 | c.84G>A p.W28* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV58971313; called by muse, mutect2, varscan2
- OR5M1 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV73202488; called by muse, mutect2, varscan2
- OR7D2 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV60141534; called by muse, mutect2, varscan2
- OTUD5 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.969); catalogued as rs1461469540, COSV50241045; called by muse, mutect2, varscan2
- OTUD7B | c.2111G>C p.G704A | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV64918134; called by muse, mutect2, varscan2
- OVCH1 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58968986; called by muse, mutect2, varscan2
- PACSIN3 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV54068211; called by muse, mutect2, varscan2
- PAM | c.1469C>T p.P490L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV57221292; called by muse, varscan2
- PAX8 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); catalogued as rs374054907; called by muse, mutect2
- PCDHA4 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.028); catalogued as rs781791401, COSV63538555; called by muse, mutect2, varscan2
- PCDHB13 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs200189405, COSV53395314; called by muse, mutect2, varscan2
- PCDHB15 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.009); catalogued as COSV51424136; called by muse, mutect2, varscan2
- PCDHB8 | c.1264A>T p.I422F | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV50830065; called by muse, mutect2
- PCSK7 | c.1013A>T p.N338I | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58009896; called by muse, mutect2, varscan2
- PDPR | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV55357745; called by muse, mutect2, varscan2
- PIP4P1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51659137; called by muse, mutect2, varscan2
- PKDREJ | c.6485T>A p.V2162D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53554127; called by muse, mutect2, varscan2
- PLA2G4A | c.1448A>T p.E483V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV66557808; called by muse, mutect2, varscan2
- PLCE1 | c.2167C>T p.L723F | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV53376210; called by muse, mutect2, varscan2
- POF1B | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53141883; called by muse, mutect2, varscan2
- POLRMT | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV73933225, COSV73933750; called by muse, mutect2, varscan2
- POTEF | c.3215G>A p.R1072H | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as rs773851327, COSV62545246; called by muse, mutect2, varscan2
- PPP2R2A | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60099540; called by muse, mutect2, varscan2
- PRKDC | c.11843C>T p.S3948F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58066892; called by muse, mutect2, varscan2
- PRLR | c.1075C>T p.L359F | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV51501449; called by muse, mutect2, varscan2
- PROM2 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs757607037, COSV58301081; called by muse, mutect2, varscan2
- PROS1 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.259); catalogued as COSV67777704; called by muse, mutect2, varscan2
- PROSER1 | c.2500C>T p.L834F | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs899542768, COSV61490097; called by muse, mutect2, varscan2
- PSD4 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55530936; called by muse, mutect2, varscan2
- PSG7 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 119/321 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368206323, COSV68446973; called by muse, mutect2, varscan2
- PTGFRN | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as COSV67798660, COSV67799840; called by muse, mutect2, varscan2
- PVRIG | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99443664; called by muse, mutect2, varscan2
- PYGL | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.481); catalogued as COSV53589577; called by muse, mutect2, varscan2
- RBM46 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55982503; called by muse, mutect2, varscan2
- RBM7 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); catalogued as COSV64956067; called by muse, mutect2, varscan2
- RNF128 | c.641C>T p.S214F (on ENST00000255499 / NM_194463.2; = p.S188F on NM_024539.3) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55255616; called by muse, mutect2, varscan2
- RNF150 | c.351G>A p.W117* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV60801267; called by muse, mutect2, varscan2
- RNF207 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.727); catalogued as COSV65008567; called by muse, mutect2, varscan2
- RPL21 | c.240T>C p.V80= | Splice Region (SNP) | VAF 39/82 reads (48%) | catalogued as COSV55389911; called by muse, mutect2, varscan2
- RPS6KA6 | c.1831C>T p.L611F | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53120141, COSV53128422; called by muse, mutect2, varscan2
- SCML2 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as COSV52625839; called by muse, mutect2, varscan2
- SCN10A | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs910976049, COSV71861052; called by muse, mutect2, varscan2
- SCUBE2 | c.2323C>T p.Q775* (on ENST00000649792 / NM_001367977.2; = p.Q718* on NM_020974.3) | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as COSV58547553; called by muse, mutect2, varscan2
- SERPINB7 | c.801G>A p.M267I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV60536426; called by muse, mutect2, varscan2
- SETD1A | c.2585C>T p.S862F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs999383883, COSV52693570; called by muse, mutect2, varscan2
- SEZ6L | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV50669401; called by muse, mutect2, varscan2
- SLC12A4 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867794431, COSV57936856; called by muse, mutect2, varscan2
- SLC16A14 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV54621984; called by muse, mutect2, varscan2
- SLC22A2 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65268433; called by muse, mutect2, varscan2
- SLC28A2 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV61665551; called by muse, mutect2
- SLC4A10 | c.1228C>T p.R410C (on ENST00000446997 / NM_001354461.2; = p.R380C on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs558073659, COSV55769372; called by muse, mutect2, varscan2
- SLC6A2 | c.666C>G p.H222Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.153); catalogued as COSV54917691, COSV54921034, COSV54924699; called by muse, mutect2, varscan2
- SLFN13 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs775664221, COSV53196066; called by muse, mutect2, varscan2
- SLIT3 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.957); catalogued as COSV60637010; called by muse, mutect2, varscan2
- SNRNP200 | c.4307C>T p.S1436F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60495382; called by muse, mutect2, varscan2
- SOS2 | c.1886A>C p.Y629S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53576049; called by muse, mutect2, varscan2
- SPEG | c.4348C>T p.R1450W | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1175171346, COSV56676247; called by muse, mutect2, varscan2
- SPTBN4 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.079); catalogued as rs978098748, COSV58960938; called by muse, mutect2, varscan2
- SSR4 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99381022; called by muse, mutect2, varscan2
- STAC | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56219860; called by muse, mutect2, varscan2
- STK32B | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51518305; called by muse, mutect2, varscan2
- SUN3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.028); catalogued as COSV52049161; called by muse, mutect2, varscan2
- SUPT6H | c.3619C>T p.P1207S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as COSV58932364; called by muse, mutect2, varscan2
- SUSD2 | c.2291C>T p.T764I | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.299); catalogued as COSV100844144; called by muse, mutect2, varscan2
- SYT3 | c.1076C>T p.T359I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58899652; called by muse, mutect2
- TACR3 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1483292600, COSV100510014; called by muse, mutect2, varscan2
- TACR3 | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100510017; called by muse, mutect2, varscan2
- TECTA | c.5564G>A p.G1855E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as rs1327019423, COSV50766447; called by muse, mutect2, varscan2
- TEDC2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1351633486, COSV99563077; called by muse, mutect2, varscan2
- TIPARP | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599664, COSV99903650; called by muse, mutect2, varscan2
- TLE1 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as rs1158922331, COSV64690027; called by muse, mutect2, varscan2
- TNS1 | c.2245C>T p.L749F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs759990832, COSV50785390; called by muse, mutect2, varscan2
- TOPORS | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62118583; called by muse, mutect2, varscan2
- TSHZ1 | c.2732C>T p.T911I (on ENST00000580243 / NM_001308210.2; = p.T866I on NM_005786.6) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59018885; called by muse, mutect2, varscan2
- TTC21A | c.2267G>A p.R756K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV57190097; called by muse, mutect2, varscan2
- TTN | c.43928G>A p.G14643E (on ENST00000591111; = p.G7219E on NM_003319.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | PolyPhen probably damaging (1); catalogued as rs794729444, COSV60410494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TWF2 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as COSV100564437; called by muse, mutect2, varscan2
- UBP1 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52148139; called by muse, mutect2, varscan2
- UBR5 | c.2429T>A p.I810N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as COSV55302651; called by muse, mutect2, varscan2
- UBR5 | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV55302665; called by muse, mutect2, varscan2
- URGCP | c.2482C>T p.P828S (on ENST00000453200 / NM_001077663.3; = p.P819S on NM_017920.4) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56253890; called by muse, mutect2, varscan2
- USH2A | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as COSV56452540; called by muse, mutect2, varscan2
- USP6 | c.2855C>T p.P952L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.96); catalogued as COSV51499742; called by muse, mutect2, varscan2
- UTP15 | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs949623747, COSV57147900; called by muse, mutect2, varscan2
- VIP | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770412296, COSV65888593; called by muse, mutect2, varscan2
- VPS13D | c.3359T>A p.V1120E | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50705738; called by muse, mutect2, varscan2
- VPS13D | c.12060G>C p.L4020F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV50705851; called by muse, mutect2, varscan2
- VRK3 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV57468424; called by muse, mutect2, varscan2
- WWC3 | c.2078T>C p.V693A | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs768795377, COSV66508774; called by muse, mutect2, varscan2
- ZDHHC6 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV65564397; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1314T>G p.C438W | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60876077; called by muse, mutect2, varscan2
- ZNF208 | c.3655C>T p.H1219Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV68101248; called by muse, mutect2, varscan2
- ZNF260 | c.142A>G p.M48V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV72951306; called by muse, mutect2, varscan2
- ZNF460 | c.1307C>T p.T436I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV64416642, COSV64416656; called by muse, mutect2, varscan2
- ZNF479 | c.755G>A p.W252* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV58644601; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.826T>G p.S276A | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.425); catalogued as COSV58675014; called by muse, mutect2, varscan2
- ZNF569 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757231883, COSV57599934; called by muse, mutect2, varscan2
- ZNF581 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.148); catalogued as COSV54401661; called by muse, mutect2, varscan2
- ZNF597 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.958); catalogued as COSV57086016; called by muse, mutect2, varscan2
- ZNF71 | c.1171T>C p.F391L | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV60150770; called by muse, mutect2, varscan2
- ZNF76 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57593107; called by muse, mutect2, varscan2
- ZNF804B | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV60862043; called by muse, mutect2, varscan2
- DISC1 | c.304del p.S102Vfs*7 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- FSIP2 | c.16274dup p.N5425Kfs*23 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- LILRB3 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ADAMTSL1 | c.519T>C p.D173= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1341942246, COSV52827636; called by muse, mutect2, varscan2
- ADCY4 | c.1260G>A p.G420= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100156143; called by muse, mutect2, varscan2
- AHSP | c.243C>T p.F81= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV56528649; called by muse, mutect2, varscan2
- AMOTL2 | c.1678C>T p.L560= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV51440880; called by muse, mutect2, varscan2
- AMOTL2 | c.1677C>T p.I559= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs760293974, COSV99850569; called by muse, mutect2, varscan2
- ASXL3 | c.5260C>T p.L1754= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV52482797; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1758G>C p.L586= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV59478279, COSV59481535; called by muse, mutect2, varscan2
- BBS7 | c.915C>T p.I305= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs776811172, COSV52655099; called by muse, mutect2, varscan2
- BOC | c.324C>T p.A108= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs914248267, COSV56359313; called by muse, mutect2, varscan2
- BRAT1 | c.780G>A p.V260= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV61397622; called by muse, mutect2, varscan2
- CASR | c.2337G>A p.K779= (on ENST00000490131; = p.K856= on NM_000388.4) | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs200036671, COSV56142251; called by muse, mutect2, varscan2
- CATSPERD | c.246C>T p.L82= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV67537950; called by muse, mutect2, varscan2
- CCDC142 | c.486C>T p.L162= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1237338920, COSV51780426; called by muse, mutect2, varscan2
- CDADC1 | c.204C>T p.P68= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV51914204; called by muse, mutect2, varscan2
- CDH20 | c.1851G>A p.L617= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV53019791; called by muse, mutect2, varscan2
- CELSR1 | c.3960C>T p.S1320= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs201238170, COSV53101927; called by muse, mutect2, varscan2
- CFHR2 | c.489C>T p.F163= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV66382448; called by muse, mutect2, varscan2
- CFHR2 | c.780G>A p.G260= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1415011030, COSV66380924; called by muse, mutect2, varscan2
- CHRDL1 | c.1020G>A p.T340= (on ENST00000372045; = p.T346= on NM_145234.4) | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as rs776403786, COSV54326684; called by muse, mutect2, varscan2
- CLCN1 | c.2739G>A p.R913= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV58375296; called by muse, mutect2, varscan2
- CLRN1 | c.15G>A p.Q5= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV58996016; called by muse, mutect2, varscan2
- CNR2 | c.468C>T p.I156= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs966768377, COSV65694937; called by muse, mutect2, varscan2
- CNTNAP3 | c.2268G>A p.K756= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99904004; called by muse, mutect2, varscan2
- COL4A5 | c.3864C>T p.G1288= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV60374411; called by muse, mutect2, varscan2
- CSN2 | c.126G>A p.E42= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100778708, COSV100778803; called by muse, mutect2, varscan2
- CYP24A1 | c.1287T>C p.F429= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV53777251; called by muse, mutect2, varscan2
- DIS3L | c.1488T>C p.N496= (on ENST00000319212 / NM_001143688.3; = p.N413= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs752522813, COSV59914876; called by muse, mutect2, varscan2
- DNAAF1 | c.1935C>T p.P645= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100499841, COSV58989869; called by muse, mutect2, varscan2
- DNAH5 | c.11832G>A p.L3944= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV54202777; called by muse, mutect2, varscan2
- DSP | c.849C>T p.I283= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV65796878; called by muse, mutect2, varscan2
- EFEMP2 | c.483G>A p.E161= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV57261800; called by muse, mutect2, varscan2
- EPB41L1 | c.2214G>A p.R738= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV52446415; called by muse, mutect2, varscan2
- EPHB2 | c.411G>A p.K137= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV65867434; called by muse, mutect2, varscan2
- ERC2 | c.2535G>A p.R845= | Silent (SNP) | VAF 43/130 reads (33%) | catalogued as rs1426124624, COSV55602966; called by muse, mutect2, varscan2
- ESRRB | c.960C>T p.L320= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV55068324; called by muse, mutect2
- FAM47B | c.6G>A p.G2= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV61456027, COSV61457255; called by muse, mutect2, varscan2
- FANCI | c.2646A>G p.L882= (on ENST00000310775 / NM_001376911.1; = p.L822= on NM_018193.3) | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs199627578, COSV55536127; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FASN | c.3501C>T p.A1167= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV60762487; called by muse, mutect2, varscan2
- FAT3 | c.1395A>G p.A465= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV53187443; called by muse, mutect2, varscan2
- FBXO34 | c.1935C>T p.S645= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV58257606; called by muse, mutect2, varscan2
- FHDC1 | c.1662C>T p.F554= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV52604130; called by muse, mutect2, varscan2
- FMN2 | c.2343C>T p.F781= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV60430109, COSV60459337; called by muse, mutect2, varscan2
- FOXK1 | c.507C>T p.F169= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV61069370; called by muse, mutect2, varscan2
- FRMPD4 | c.783C>T p.L261= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as COSV66225178; called by muse, mutect2, varscan2
- GCM1 | c.63G>A p.V21= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV52524383; called by muse, mutect2, varscan2
- GGT6 | c.330C>T p.I110= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs377047398; called by muse, mutect2, varscan2
- GSTA1 | c.516C>T p.S172= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs1051873, COSV58016353; called by muse, mutect2, varscan2
- HNRNPA0 | c.333G>A p.E111= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV59247073; called by muse, mutect2, varscan2
- HSPA9 | c.369C>T p.L123= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV51866859, COSV99785265; called by muse, mutect2, varscan2
- ICAM1 | c.96C>T p.S32= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV53427743; called by muse, mutect2, varscan2
- IGLV3-16 | c.114G>A p.R38= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs995283278; called by muse, mutect2, varscan2
- ILDR1 | c.1626G>A p.R542= (on ENST00000344209 / NM_001199799.2; = p.R498= on NM_175924.4) | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs763466435, COSV56551103; called by muse, mutect2, varscan2
- ITGAX | c.274C>T p.L92= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV51652963; called by muse, mutect2, varscan2
- KCTD2 | c.615C>T p.S205= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1250592181, COSV100483221; called by muse, mutect2, varscan2
- KDM5B | c.2830C>T p.L944= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99349982; called by muse, mutect2, varscan2
- KDM5B | c.2829C>T p.D943= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99349984; called by muse, mutect2, varscan2
- KIF27 | c.2877G>A p.K959= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV99926586; called by muse, mutect2, varscan2
- KIF4B | c.3063C>T p.I1021= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs1370295040, COSV70527125; called by muse, mutect2, varscan2
- KLK6 | c.321C>T p.I107= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs868388467, COSV59566374; called by muse, mutect2
- KRT25 | c.966C>T p.S322= | Silent (SNP) | VAF 47/139 reads (34%) | catalogued as COSV56446975; called by muse, mutect2, varscan2
- LCE2B | c.162C>T p.G54= | Silent (SNP) | VAF 88/221 reads (40%) | catalogued as COSV64227513; called by muse, mutect2, varscan2
- LHFPL6 | c.141C>T p.F47= | Silent (SNP) | VAF 66/159 reads (42%) | catalogued as COSV65449945; called by muse, mutect2, varscan2
- LILRA1 | c.606G>A p.S202= | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as rs766261549, COSV52177613; called by muse, varscan2
- LILRA5 | c.831G>A p.V277= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV56645705; called by muse, mutect2, varscan2
- LMAN2 | c.994C>T p.L332= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV57426216; called by muse, mutect2, varscan2
- LPCAT4 | c.1296C>A p.G432= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100148811; called by muse, mutect2, varscan2
- LRRC32 | c.399G>A p.G133= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs142130044, COSV52636313; called by muse, mutect2, varscan2
- LRRC45 | c.1990A>C p.R664= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV60713148; called by muse, mutect2, varscan2
- MED24 | c.2067C>T p.S689= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100672944; called by muse, mutect2, varscan2
- MOB2 | c.105C>T p.F35= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1181157202, COSV57319719; called by muse, mutect2, varscan2
- MOV10L1 | c.3408C>T p.I1136= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs777536018, COSV53181211; called by muse, mutect2, varscan2
- NCOR2 | c.933G>A p.K311= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs1422400286, COSV62306189; called by muse, mutect2, varscan2
- NPHP1 | c.474C>T p.I158= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs1253817401, COSV57212193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NT5C3B | c.720G>A p.G240= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV54057847; called by muse, mutect2, varscan2
- NUP210 | c.4665G>A p.Q1555= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs1559305357, COSV54413408; called by muse, mutect2, varscan2
- OLFM1 | c.1152C>T p.P384= (on ENST00000371793 / NM_001282611.2; = p.P366= on NM_014279.5) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs373065602; called by muse, mutect2, varscan2
- OR10K1 | c.42C>T p.V14= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs1463895839, COSV56874289; called by muse, mutect2, varscan2
- OR10P1 | c.870C>T p.I290= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV59008643; called by muse, mutect2, varscan2
- OR2G3 | c.813G>A p.G271= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV60682370; called by muse, mutect2, varscan2
- OR4C12 | c.180C>T p.F60= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV58859427; called by muse, mutect2, varscan2
- OR51F1 | c.192C>T p.L64= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs913700912, COSV58581163; called by muse, mutect2, varscan2
- OR5D13 | c.777C>T p.F259= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV62332974; called by muse, mutect2, varscan2
- OR8H2 | c.126G>A p.G42= | Silent (SNP) | VAF 83/227 reads (37%) | catalogued as rs142929368; called by muse, mutect2, varscan2
- OR8J3 | c.123G>A p.G41= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as rs926252328, COSV56884176; called by muse, mutect2, varscan2
- P4HA3 | c.921C>T p.T307= | Silent (SNP) | VAF 86/192 reads (45%) | catalogued as COSV59044497; called by muse, mutect2, varscan2
- PALD1 | c.2241C>T p.I747= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as COSV54979944; called by muse, mutect2, varscan2
- PCDHA1 | c.1494G>A p.R498= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs368150526; called by muse, mutect2, varscan2
- PCDHB7 | c.1984C>T p.L662= | Silent (SNP) | VAF 33/471 reads (7%) | catalogued as COSV50830062; called by muse, mutect2
- PCDHGA7 | c.225C>T p.F75= | Silent (SNP) | VAF 50/97 reads (52%) | catalogued as COSV54053472; called by muse, mutect2, varscan2
- PCNX2 | c.1230T>C p.A410= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as COSV50940180; called by muse, mutect2, varscan2
- PCSK1 | c.1755G>A p.V585= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV60738024; called by muse, mutect2, varscan2
- PDE5A | c.393G>A p.K131= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV53354222; called by muse, mutect2, varscan2
- PECR | c.858C>T p.D286= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV54736215; called by muse, mutect2, varscan2
- PHETA1 | c.147C>T p.F49= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs539578907, COSV64059077; called by muse, mutect2, varscan2
- PHF12 | c.2307A>T p.S769= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV52022728; called by muse, mutect2, varscan2
- PIP4K2A | c.171C>T p.I57= | Silent (SNP) | VAF 28/41 reads (68%) | catalogued as rs1286625197, COSV64862507, COSV64865710; called by muse, mutect2, varscan2
- POLR1A | c.3318G>A p.E1106= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV55700825; called by muse, mutect2, varscan2
- PRDM1 | c.774C>T p.S258= | Silent (SNP) | VAF 104/164 reads (63%) | catalogued as COSV64847388; called by muse, mutect2, varscan2
- PRKDC | c.954C>T p.S318= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV58061904; called by muse, mutect2, varscan2
- PSD | c.705C>T p.I235= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs757010456, COSV50050441, COSV50068454; called by muse, mutect2, varscan2
- PSME3 | c.717C>T p.I239= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs202070240, COSV53198477; called by muse, mutect2, varscan2
- PVRIG | c.603C>T p.A201= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs771539454, COSV99443661; called by muse, mutect2, varscan2
- PYGL | c.1026C>T p.H342= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV53589568; called by muse, mutect2, varscan2
- RBM19 | c.423G>A p.Q141= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV55700176; called by muse, mutect2, varscan2
- RBM46 | c.1590C>T p.A530= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV55982515; called by muse, mutect2, varscan2
- RP1 | c.1839C>T p.T613= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV55128991; called by muse, mutect2, varscan2
- SDK2 | c.2631C>G p.P877= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV66183553, COSV66198910; called by muse, mutect2, varscan2
- SH3D21 | c.2229C>T p.S743= (on ENST00000453908 / NM_001162530.2; = p.S632= on NM_024676.5) | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV54635771; called by muse, mutect2, varscan2
- SHANK2 | c.3429C>T p.S1143= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs1396525140, COSV53586909, COSV53593653; called by muse, mutect2, varscan2
- SIVA1 | c.165C>T p.D55= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV57332217; called by muse, mutect2, varscan2
- SLC12A3 | c.669C>T p.F223= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs779986569, COSV52633150; called by muse, mutect2, varscan2
- SLC16A14 | c.654A>G p.P218= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV54621999; called by muse, mutect2, varscan2
- SLC52A2 | c.795C>T p.D265= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV57353870; called by muse, mutect2, varscan2
- SLC7A13 | c.102C>T p.S34= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV52538164, COSV99878600; called by muse, mutect2, varscan2
- SLC9A2 | c.1293C>T p.I431= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV52132226; called by muse, mutect2, varscan2
- SLC9C1 | c.3372T>C p.V1124= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV59894747; called by muse, mutect2, varscan2
- SNCAIP | c.2295C>T p.G765= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1366389103, COSV54423674; called by muse, mutect2, varscan2
- SPAG5 | c.1311C>T p.N437= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs1300892914, COSV58805397; called by muse, mutect2, varscan2
- SPATA21 | c.499C>T p.L167= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1425776670, COSV59189092; called by muse, mutect2, varscan2
- SPHKAP | c.2217G>A p.K739= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as COSV60873876; called by muse, mutect2, varscan2
- SSR4 | c.360G>A p.R120= | Silent (SNP) | VAF 57/212 reads (27%) | catalogued as rs782642605, COSV99381023; called by muse, mutect2, varscan2
- STATH | c.36C>T p.L12= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV55894388; called by muse, mutect2, varscan2
- STXBP4 | c.624C>T p.S208= | Silent (SNP) | VAF 160/430 reads (37%) | catalogued as COSV54844398; called by muse, mutect2, varscan2
- SUSD2 | c.2292C>T p.T764= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV100844146; called by muse, mutect2, varscan2
- SUSD4 | c.660G>C p.A220= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV59557402; called by muse, mutect2, varscan2
- TAF1L | c.846G>A p.R282= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as COSV54264792; called by muse, mutect2, varscan2
- TBC1D9B | c.928C>T p.L310= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV62284360; called by muse, mutect2, varscan2
- TEDC2 | c.555C>T p.A185= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99563080; called by muse, mutect2, varscan2
- TENM2 | c.3426T>C p.A1142= (on ENST00000518659 / NM_001122679.2; = p.A910= on NM_001080428.3) | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV69144299; called by muse, mutect2, varscan2
- TMPRSS11B | c.642G>A p.L214= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV60291112; called by muse, mutect2
- TP63 | c.642G>A p.K214= | Silent (SNP) | VAF 53/130 reads (41%) | catalogued as COSV53223671; called by muse, mutect2, varscan2
- TPCN2 | c.849C>T p.S283= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV53734538, COSV99593855; called by muse, mutect2, varscan2
- TRIM59 | c.1002A>G p.V334= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV59088824; called by muse, mutect2, varscan2
- TRPC5 | c.2328A>G p.E776= | Silent (SNP) | VAF 110/288 reads (38%) | catalogued as COSV53304954; called by muse, mutect2, varscan2
- TUBA3C | c.276G>A p.L92= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV67140206; called by muse, mutect2, varscan2
- TWF2 | c.1023C>T p.G341= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV100564438; called by muse, mutect2, varscan2
- UBN1 | c.2520C>T p.S840= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV52173996; called by muse, mutect2, varscan2
- UNC13A | c.3402C>T p.F1134= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV53214107; called by muse, mutect2, varscan2
- USP20 | c.2493C>T p.F831= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs1013380026, COSV59611008; called by muse, mutect2, varscan2
- USP26 | c.1680C>T p.P560= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV63710067; called by muse, mutect2, varscan2
- VPS37B | c.513G>A p.Q171= | Silent (SNP) | VAF 50/108 reads (46%) | catalogued as COSV53445661; called by muse, mutect2, varscan2
- WDR18 | c.1293C>T p.A431= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV52123955; called by muse, mutect2, varscan2
- ZAN | c.6906G>A p.G2302= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV61818421; called by muse, mutect2, varscan2
- ZC3HAV1L | c.420G>A p.L140= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV51965255; called by muse, mutect2, varscan2
- ZNF585B | c.2262C>T p.G754= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs1183395007, COSV57217347; called by muse, mutect2, varscan2
- ZNF714 | c.807T>C p.P269= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs764207057, COSV52516381; called by muse, mutect2, varscan2
- ZNF761 | c.1692C>T p.T564= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV61889676; called by muse, mutect2, varscan2
- BIRC8 | n.1416G>A | RNA (SNP) | VAF 36/116 reads (31%) | catalogued as COSV70347456, COSV70348200; called by muse, mutect2, varscan2
- CCSER1 | c.2094+23096del | Intron (DEL) | VAF 42/154 reads (27%) | called by pindel, varscan2
- CLDN16 | chr3:190388150 G>A | 5'Flank (SNP) | VAF 5/20 reads (25%) | catalogued as COSV53229632; called by muse, mutect2, varscan2
- CT45A3 | c.*1G>A | 3'UTR (SNP) | VAF 16/496 reads (3%) | called by muse, mutect2
- IGF1R | c.*2C>T | 3'UTR (SNP) | VAF 19/51 reads (37%) | catalogued as COSV99148365; called by muse, mutect2, varscan2
- MIR216B | n.22G>A | RNA (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- NRG1 | c.502+30980G>A | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99827473; called by muse, mutect2, varscan2
- NRG1 | c.502+30981G>A | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as COSV55163283; called by muse, mutect2, varscan2
- OSGIN1 | n.1254C>T | RNA (SNP) | VAF 42/90 reads (47%) | catalogued as COSV59423607, COSV59424028; called by muse, mutect2, varscan2
- RAB13 | c.*1G>A | 3'UTR (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99665581; called by muse, mutect2, varscan2
- TAS2R5 | c.*2C>A | 3'UTR (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99924743; called by muse, mutect2, varscan2
